Gene-level copy-number profile of tumor specimen TCGA-04-1351-01A from TCGA case TCGA-04-1351, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.8 years (28,045 days).
Specimen TCGA-04-1351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3b948e06-a6e7-439a-9a49-63e921749f39.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1351-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 410 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7319173-7bca-4a31-b3ce-4c80662b3cf4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 478; copy number 2: 2,582; copy number 3: 21,943; copy number 4: 19,550; copy number 5: 6,392; copy number 6: 2,775; copy number 7: 1,671; copy number 8: 1,556; copy number 9: 356; copy number 10: 791; copy number 11: 85; copy number 12: 237; copy number 13: 255; copy number 15: 239; copy number 16: 513; copy number 17: 262; copy number 25: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1351-01): tumor purity 0.72, ploidy 4.37, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,973 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,790,422–36,483,278, 142 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr4:13,654,374–15,853,232, 28 genes, copy number 7 (within-gene range 4–7): LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38.
- chr4:20,251,905–20,752,907, 4 genes, copy number 8 (within-gene range 6–8): SLIT2, SLIT2-IT1, MIR218-1, PACRGL.
- chr4:20,766,808–20,767,372, 1 gene, copy number 8: AC097505.1.
- chr4:55,798,636–56,821,742, 32 genes, copy number 7: RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA.
- chr4:68,509,441–68,568,527, 2 genes, copy number 10: UGT2B29P, UGT2B17.
- chr7:15,611,212–42,844,438, 477 genes, copy number 10–17 (broad region; genes not listed).
- chr8:42,836,674–46,028,892, 36 genes, copy number 7–8: THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr8:49,496,763–86,818,558, 558 genes, copy number 10–16 (broad region; genes not listed).
- chr8:108,131,100–108,787,594, 9 genes, copy number 7: AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:114,791,653–114,791,929, 1 gene, copy number 13: CARS1P2.
- chr9:26,947,039–27,066,134, 1 gene, copy number 10 (within-gene range 2–10): IFT74.
- chr9:26,993,136–27,944,497, 16 genes, copy number 10: LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:60,914,407–63,385,117, 68 genes, copy number 8–9 (broad region; genes not listed).
- chr10:93,284,004–98,446,947, 118 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 12–25 (broad region; genes not listed).
- chr12:51,590,266–52,309,163, 32 genes, copy number 7 (within-gene range 4–7): SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3.
- chr12:52,377,812–52,520,530, 10 genes, copy number 7: KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5.
- chr12:66,023,620–73,208,317, 133 genes, copy number 8 (broad region; genes not listed).
- chr12:75,040,077–75,209,839, 1 gene, copy number 10 (within-gene range 5–10): KCNC2.
- chr13:26,557,683–114,337,626, 1,182 genes, copy number 7–8 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,419 genes, copy number 8–17 (broad region; genes not listed).
- chr20:25,006,230–36,646,196, 284 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:36,668,559–36,668,670, 1 gene, copy number 7: Y_RNA.
- chr20:41,991,140–52,670,578, 278 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:52,972,358–64,313,132, 290 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
